Somatic mutation profile of tumor specimen 0DD872 from CCDI case PBBNKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,698 days).
Specimen 0DD872: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44b8bd73-ba42-4b12-9109-b8cbb0c8c104.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD86W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/570f0418-8e24-4701-a7ac-32abc8b74708

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3, 3'UTR 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 74/213 reads (35%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 173/416 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 345/477 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- NF1 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 94/279 reads (34%) | catalogued as rs786203950, CM087437, CS983483, COSV62192041, COSV62210573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 132/378 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 172/443 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54664896, COSV99591429; called by muse, mutect2, varscan2
- FFAR1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199506594, COSV50050607; called by muse, mutect2, varscan2
- OR4M1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 117/780 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV60059787; called by muse, mutect2, varscan2
- TCEAL5 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 107/300 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs971265296; called by muse, mutect2, varscan2
- TDP2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 185/548 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV57765811; called by muse, mutect2, varscan2
- AFF2 | c.591T>G p.F197L | Missense Mutation (SNP) | VAF 164/478 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- NF1 | c.3782_3786del p.F1261* | Frame Shift Del (DEL) | VAF 130/374 reads (35%) | called by mutect2, varscan2
- PAX3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 182/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TANGO2 | c.695C>G p.P232R | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- UBR5 | c.1446C>G p.Y482* | Nonsense Mutation (SNP) | VAF 185/476 reads (39%) | called by muse, mutect2, varscan2
- A4GALT | c.405C>T p.C135= | Silent (SNP) | VAF 116/334 reads (35%) | catalogued as COSV99966635; called by muse, mutect2, varscan2
- CALCA | c.9C>T p.F3= | Silent (SNP) | VAF 186/508 reads (37%) | catalogued as COSV59027377; called by muse, mutect2, varscan2
- GAL3ST1 | c.816C>T p.D272= | Silent (SNP) | VAF 132/409 reads (32%) | catalogued as rs1306346945; called by muse, mutect2, varscan2
- HTR1E | c.420G>A p.A140= | Silent (SNP) | VAF 187/467 reads (40%) | catalogued as rs769674442; called by muse, mutect2, varscan2
- IQCH | c.2151C>T p.H717= | Silent (SNP) | VAF 85/223 reads (38%) | catalogued as rs552590760; called by muse, mutect2, varscan2
- KCTD3 | c.1747+41C>G | Intron (SNP) | VAF 131/450 reads (29%) | called by muse, mutect2, varscan2
- KIAA1614 | c.*3C>T | 3'UTR (SNP) | VAF 119/380 reads (31%) | catalogued as rs202098581; called by muse, mutect2, varscan2
